Somatic mutation profile of tumor specimen TCGA-ZF-A9RM-01A (aliquot TCGA-ZF-A9RM-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9RM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 70.2 years (25,642 days).
Specimen TCGA-ZF-A9RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce6d3b36-d5e2-45d7-8f1f-64c7e5886c4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RM-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RM-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fc8b64a-738b-42a6-a9aa-93ce4e3b597a

The open-access MAF lists 91 somatic variants for this specimen: 69 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, Nonsense Mutation 4, Frame Shift Del 3, RNA 1, Splice Site 1, 5'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 21/22 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV53625895; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV65894176; called by muse, mutect2, varscan2
- ADGRV1 | c.11038C>T p.R3680C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367738566; called by muse, mutect2, varscan2
- AFDN | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs201634310, COSV60048639; called by muse, mutect2, varscan2
- ANK2 | c.1620G>C p.E540D | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV52171690; called by muse, mutect2, varscan2
- BOD1L1 | c.5618G>A p.S1873N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV50024103; called by muse, mutect2, varscan2
- CACNA1S | c.4039G>A p.G1347R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755381, COSV62941322; called by muse, mutect2, varscan2
- CDHR2 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 5/91 reads (5%) | catalogued as COSV99992308; called by muse, mutect2
- CLMN | c.2970C>A p.C990* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100113076; called by mutect2, varscan2
- CLMN | c.1892C>G p.P631R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as COSV54184394; called by muse, mutect2, varscan2
- CLMN | c.1665T>A p.Y555* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100113078; called by muse, mutect2, varscan2
- CREB5 | c.428T>A p.V143D (on ENST00000357727 / NM_182898.4; = p.V136D on NM_004904.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63223987; called by muse, mutect2, varscan2
- CTNND2 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.47); catalogued as rs1479743979, COSV58903542; called by muse, mutect2, varscan2
- DDR2 | c.2434A>G p.T812A | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV63372222; called by muse, mutect2
- EDIL3 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV56906560; called by muse, mutect2, varscan2
- ELF3 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62839171; called by muse, mutect2, varscan2
- ERICH6 | c.1373G>C p.R458P | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as COSV55801626; called by muse, mutect2, varscan2
- ERLEC1 | c.757G>C p.A253P | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51752507; called by muse, mutect2, varscan2
- FOXM1 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1200476575, COSV61206597; called by muse, mutect2, varscan2
- GRB10 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.259); catalogued as COSV60012579; called by muse, mutect2, varscan2
- HMGCS1 | c.1197T>A p.D399E | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57290705; called by muse, mutect2
- HYOU1 | c.2492A>G p.H831R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.482); catalogued as rs1403140386, COSV68216451; called by muse, mutect2, varscan2
- IFT88 | c.919A>G p.I307V (on ENST00000319980 / NM_001318493.2; = p.I298V on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs769108016, COSV60674863; called by muse, mutect2, varscan2
- IL18R1 | c.1077T>G p.Y359* | Nonsense Mutation (SNP) | VAF 31/59 reads (53%) | catalogued as COSV99295568; called by muse, mutect2, varscan2
- IQSEC3 | c.2891C>T p.S964L (on ENST00000538872 / NM_001170738.2; = p.S661L on NM_015232.1) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV58286986; called by muse, mutect2, varscan2
- KIR2DL3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 128/379 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV100668164; called by muse, mutect2, varscan2
- KLF3 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as COSV54711457; called by muse, mutect2, varscan2
- KLHDC7B | c.1292G>A p.R431H (on ENST00000395676; = p.R1072H on NM_138433.5) | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs752119633, COSV67464866; called by muse, mutect2, varscan2
- KMT5B | c.2606T>C p.I869T | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58567647; called by muse, mutect2, varscan2
- LRP1B | c.11398C>A p.P3800T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV67244461; called by mutect2, varscan2
- LRRC37A3 | c.3350C>A p.T1117N | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58534219, COSV58535901; called by muse, mutect2
- LRRIQ3 | c.584A>T p.Y195F | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV100599603; called by muse, mutect2
- LRRN4 | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.569); catalogued as COSV66645930; called by muse, mutect2, varscan2
- MCAM | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs770572311, COSV50644671, COSV99876078; called by muse, mutect2, varscan2
- NACA2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs1298768878, COSV101478554, COSV71713152; called by muse, mutect2
- NAGA | c.84G>C p.M28I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67170059, COSV67170374; called by muse, mutect2, varscan2
- OBSCN | c.3971A>T p.D1324V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52792500; called by muse, mutect2, varscan2
- OPRL1 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV61092164; called by muse, mutect2, varscan2
- OR2M2 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV62898758; called by muse, mutect2, varscan2
- OR5V1 | c.589T>G p.L197V | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV65828807; called by muse, mutect2, varscan2
- PATZ1 | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53230073; called by muse, mutect2
- PCDHB1 | c.2386C>A p.P796T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV60631838; called by muse, mutect2, varscan2
- PIBF1 | c.1960G>A p.V654I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1341887215, COSV58325115; called by muse, mutect2, varscan2
- PLRG1 | c.1485+1G>T p.X495_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | catalogued as rs1345871669, COSV57424047; called by muse, varscan2
- PPP1R1B | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV54202427; called by muse, mutect2, varscan2
- RAB11FIP1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.493); catalogued as COSV99770641; called by muse, mutect2
- RAPGEF3 | c.2473A>G p.I825V (on ENST00000389212; = p.I783V on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.583); catalogued as COSV50215638; called by muse, mutect2, varscan2
- RHOA | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV69041535, COSV69043016; called by muse, mutect2, varscan2
- RINT1 | c.2227T>G p.S743A | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV57559276; called by muse, mutect2
- RPE | c.400C>G p.Q134E (on ENST00000359429 / NM_001318926.1; = p.Q84E on NM_006916.2) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55993903; called by muse, mutect2, varscan2
- SF1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57115480; called by muse, mutect2, varscan2
- SF1 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57112550, COSV57113891, COSV57115514; called by muse, mutect2, varscan2
- SLC25A20 | c.529A>T p.M177L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1397431446, COSV59803615; called by muse, mutect2, varscan2
- SLC6A7 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs770458246, COSV57937780; called by muse, mutect2, varscan2
- SOX2 | c.251del p.E84Gfs*19 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as COSV57622455; called by mutect2, pindel, varscan2
- SRCAP | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1170509653, COSV52675871; called by muse, mutect2, varscan2
- TECPR2 | c.2086A>G p.N696D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV63971757; called by muse, mutect2, varscan2
- TIMM17A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756338629, COSV66171189; called by muse, mutect2, varscan2
- TSFM | c.807_808del p.L270* (on ENST00000323833 / NM_001172696.2; = p.L249* on NM_005726.6) | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as COSV57682584; called by mutect2, pindel, varscan2
- UACA | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59853011, COSV59857300; called by muse, mutect2
- VIRMA | c.1058G>C p.C353S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.448); catalogued as COSV52587372; called by muse, mutect2
- VPS8 | c.224C>G p.T75S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.014); catalogued as COSV99804440; called by muse, mutect2
- WWC3 | c.297G>A p.R99= | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as COSV101080859, COSV66504721; called by muse, mutect2, varscan2
- ZNF510 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV56297968; called by muse, mutect2, varscan2
- ZNF521 | c.2251G>C p.V751L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64128828; called by muse, mutect2, varscan2
- ZNF705A | c.700G>T p.G234W | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63733426; called by muse, mutect2, varscan2
- ZW10 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV52317626; called by muse, mutect2, varscan2
- SPAG17 | c.1771_1792del p.S591Pfs*10 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel
- ADCY1 | c.1918C>T p.L640= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV52037594; called by muse, mutect2, varscan2
- ADGRG5 | c.1455G>T p.L485= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1334616121, COSV61083830; called by muse, mutect2, varscan2
- CKM | c.882C>A p.G294= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs752715405, COSV53465669, COSV99488397; called by muse, mutect2, varscan2
- DACT1 | c.1374A>T p.P458= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV60021854; called by muse, mutect2, varscan2
- DMBT1 | c.7155C>T p.N2385= (on ENST00000338354 / NM_001377530.1; = p.N1628= on NM_004406.3) | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV57550010; called by muse, mutect2, varscan2
- DNAH11 | c.5481T>C p.F1827= | Silent (SNP) | VAF 135/297 reads (45%) | catalogued as COSV60965059; called by muse, mutect2, varscan2
- DUSP3 | c.408C>T p.I136= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs765209188, COSV56825089; called by muse, mutect2, varscan2
- GPER1 | c.909C>T p.P303= | Silent (SNP) | VAF 4/85 reads (5%) | catalogued as COSV99867509; called by muse, mutect2
- GRXCR2 | c.291A>C p.A97= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV65060738, COSV65061485; called by muse, mutect2
- HMCN1 | c.13086A>C p.P4362= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV54914896; called by muse, mutect2, varscan2
- LRRK2 | c.3402A>G p.L1134= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV54159534; called by muse, mutect2, varscan2
- NKX2-2 | c.153C>A p.G51= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1039197296, COSV65819380; called by muse, mutect2, varscan2
- NPAP1 | c.402G>A p.A134= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV61505707, COSV61509662, COSV61512243; called by muse, mutect2, varscan2
- PCDHGB1 | c.363A>G p.Q121= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV53979377; called by muse, mutect2
- PCDHGC4 | c.630G>A p.L210= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV52757573; called by muse, mutect2, varscan2
- RGS22 | c.2487A>G p.L829= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV62664147; called by muse, mutect2
- RYR3 | c.6198C>T p.H2066= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs750012770, COSV66798458; called by muse, mutect2, varscan2
- SLC36A2 | c.807C>T p.F269= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs764490470, COSV58863980; called by muse, mutect2, varscan2
- TLE3 | c.514C>T p.L172= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs768792642, COSV58171435; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827405 G>A | 3'Flank (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2, varscan2
- SH2D6 | n.628T>C | RNA (SNP) | VAF 23/39 reads (59%) | catalogued as COSV61064064; called by muse, mutect2, varscan2
- ZNF493 | c.-61A>G | 5'UTR (SNP) | VAF 65/138 reads (47%) | catalogued as COSV62750759; called by muse, mutect2, varscan2
